Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KV, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KV-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, Adrenal Cortical 8370/3

Site: D Adrenal Gland Cortex C74.0

9/2/13

Procedure: left adrenalectomy

Gross description: 12 x 11 x 11cm, 641g

Diagnosis: adrenocortical carcinoma, well differentiated, G1

Reference Pathology: none

4/12/13- Per new path, Weiss = 3
with LN involvement = Malignant
Process - if path set more path
May not ship if not malignant

ICD-O Discrepancy		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated
Left

Tumor size(s)
12x11x12cm

Histologic diagnosis
ACC

Lymph Node Status
1/x

Pathologic information
T2N1Mx

Weiss score
Min. 3

Source: NCI Genomic Data Commons file 209fd763-0df8-4740-8ed8-782a85066322 (TCGA-OR-A5KV.D85CC5BA-0A85-4BCB-8088-9EBA37211501.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).